Somatic mutation profile of tumor specimen C3N-00545-03 (aliquot CPT0066910006) from CPTAC case C3N-00545, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.2 years (21,607 days).
Specimen C3N-00545-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c216fe3b-6eff-4e11-8750-a8b084cf9bad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00545-71 (Blood Derived Normal), aliquot CPT0067010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fba477d5-b39b-4f5f-9128-fb5cb3686078

The open-access MAF lists 462 somatic variants for this specimen: 310 protein-altering or splice-affecting, 86 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 86, Intron 36, Nonsense Mutation 17, RNA 11, Splice Site 10, 5'UTR 7, Frame Shift Del 6, 3'UTR 6, 3'Flank 3, 5'Flank 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/399 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 22/283 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACTB | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 59/522 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59318528; called by muse, mutect2, varscan2
- ADCY1 | c.2203C>A p.L735M | Missense Mutation (SNP) | VAF 66/657 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV52034981, COSV52039400; called by muse, mutect2, varscan2
- AGBL1 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101222919; called by muse, mutect2
- ALPK2 | c.4105G>A p.V1369I | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs760732329; called by muse, mutect2
- AMPH | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57749717; called by muse, mutect2, varscan2
- ASTN2 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57770268; called by muse, mutect2, varscan2
- C17orf67 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 34/515 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as rs766096754, COSV101190892; called by muse, mutect2
- CACNA1E | c.5244G>T p.W1748C | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62401840; called by muse, mutect2, varscan2
- CACNB1 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.202); catalogued as COSV59999992; called by muse, mutect2
- CD109 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs753896488; called by muse, mutect2, varscan2
- CMA1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV51625360; called by muse, mutect2
- CNBD1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1312301463; called by muse, mutect2
- COL11A1 | c.1350+1G>T p.X450_splice | Splice Site (SNP) | VAF 31/234 reads (13%) | catalogued as COSV100617330, COSV62196797; called by muse, mutect2, varscan2
- COL13A1 | c.383del p.G128Efs*67 | Frame Shift Del (DEL) | VAF 40/375 reads (11%) | catalogued as COSV100637468; called by mutect2, pindel, varscan2
- COL18A1 | c.2242G>A p.V748M (on ENST00000359759 / NM_130444.3; = p.V513M on NM_030582.4) | Missense Mutation (SNP) | VAF 36/558 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs367882523; called by muse, mutect2
- CPED1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60007522; called by muse, mutect2
- CTNND2 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV58923270; called by muse, mutect2, varscan2
- CXorf58 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191542694, COSV101003125, COSV64858528; called by muse, mutect2
- CYP7B1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 51/309 reads (17%) | catalogued as CM1514278; called by muse, mutect2, varscan2
- DAPL1 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1402622369; called by muse, mutect2
- DCLK3 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV69363264; called by muse, mutect2
- DNMT1 | c.4445G>T p.G1482V | Missense Mutation (SNP) | VAF 57/579 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746932608; called by muse, mutect2
- FAM98B | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs1032366853; called by muse, mutect2, varscan2
- FAT3 | c.12669G>T p.Q4223H | Missense Mutation (SNP) | VAF 61/598 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV53154620; called by muse, mutect2, varscan2
- FCRLA | c.362G>T p.R121L (on ENST00000367959; = p.R98L on NM_032738.4) | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99375701; called by muse, mutect2
- FIS1 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99778874; called by muse, mutect2, varscan2
- GPATCH1 | c.1789G>T p.A597S | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767956563; called by muse, mutect2, varscan2
- GRIN2B | c.3403G>T p.D1135Y | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV74207234; called by muse, mutect2, varscan2
- GRIN2B | c.1147T>A p.S383T | Missense Mutation (SNP) | VAF 96/634 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs199671864, COSV74207529; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- HAUS6 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476458428, COSV100997936; called by muse, mutect2, varscan2
- HECW2 | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99646035, COSV99647836; called by muse, mutect2
- HHAT | c.556del p.E186Sfs*52 | Frame Shift Del (DEL) | VAF 99/625 reads (16%) | catalogued as COSV99805159; called by mutect2, pindel, varscan2
- HMCN2 | c.5386G>T p.G1796C | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320454575; called by muse, mutect2, varscan2
- IGHM | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT deleterious (0.01); catalogued as rs1398324382; called by muse, mutect2
- IGKV1D-8 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as rs367822287; called by muse, mutect2
- IMPG2 | c.2941A>G p.M981V | Missense Mutation (SNP) | VAF 74/755 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs926472701; called by muse, mutect2
- ITLN2 | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 39/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63537732; called by muse, mutect2, varscan2
- JUP | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 37/1138 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103173, COSV60278251; called by muse, mutect2
- KLHL34 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV101069961; called by muse, mutect2
- KRTAP13-2 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1228452988; called by muse, mutect2
- LMLN | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs868151000; called by muse, mutect2, varscan2
- LMNTD2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 54/376 reads (14%) | catalogued as rs767951054; called by muse, mutect2, varscan2
- LRFN5 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 19/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53254064; called by muse, mutect2
- LRRC15 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 56/578 reads (10%) | catalogued as rs755593413, COSV61649909; called by muse, mutect2
- MACC1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 10/115 reads (9%) | catalogued as COSV60545326; called by muse, mutect2
- MAEL | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 37/471 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs756146420, COSV100901555; called by muse, mutect2
- MAGEB6 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV66872140, COSV66872143; called by muse, mutect2, varscan2
- MAGEC1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53581631; called by muse, mutect2
- MROH2A | c.2591C>A p.P864Q | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV67680924; called by muse, mutect2
- MROH2B | c.1348C>A p.L450I | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1473627860; called by muse, mutect2, varscan2
- MROH5 | c.2525G>A p.S842N | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV71301851; called by muse, mutect2
- MYO16 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 54/358 reads (15%) | catalogued as COSV51814391; called by muse, mutect2, varscan2
- NAP1L2 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV65172988; called by muse, mutect2, varscan2
- NOTCH4 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV66684326; called by muse, mutect2, varscan2
- NR0B1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.876); catalogued as rs761749382; called by muse, mutect2, varscan2
- OR10X1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1164493767, COSV63767516; called by muse, mutect2
- OR2AG2 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs763024632, COSV58455444; called by muse, mutect2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OTOG | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 71/530 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1378612394; called by muse, mutect2, varscan2
- PAMR1 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.1); catalogued as rs751297404; called by muse, mutect2
- PAPPA2 | c.4466G>T p.C1489F | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62794953; called by muse, mutect2
- PNLIP | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65040864; called by muse, mutect2
- PNLIPRP1 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330443894; called by muse, mutect2
- POMT2 | c.1117-8C>T | Splice Region (SNP) | VAF 20/188 reads (11%) | catalogued as rs1399704302; called by muse, mutect2, varscan2
- PTPRQ | c.4055C>T p.T1352I (on ENST00000616559; = p.T1310I on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as rs1170285261; called by muse, mutect2
- RP1L1 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs767785821, COSV61445796; called by muse, mutect2, varscan2
- RUNX1T1 | c.1680G>T p.Q560H (on ENST00000265814 / NM_001198628.1; = p.Q533H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/965 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV56137349; called by muse, mutect2, varscan2
- RXFP1 | c.1907C>G p.T636S | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.383); catalogued as rs778181794; called by muse, mutect2
- RYR2 | c.12676C>A p.P4226T | Missense Mutation (SNP) | VAF 26/794 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1293881648, COSV63670303; called by muse, mutect2
- SAMD9L | c.1442G>T p.W481L | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs763034101, COSV59080895, COSV59080935; called by muse, mutect2
- SF3B1 | c.2222A>T p.K741M | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59205738; called by muse, mutect2
- SH2B1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs745614421; called by muse, mutect2, varscan2
- SLC25A48 | c.871G>T p.V291L (on ENST00000650267; = p.G240= on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.079); catalogued as rs1480932494; called by muse, mutect2, varscan2
- SLC6A17 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as rs1334090420; called by muse, mutect2
- SMARCC2 | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57219407, COSV57223308, COSV57224307; called by muse, mutect2, varscan2
- SOX17 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 97/602 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs575311838; called by mutect2, varscan2
- SPATA18 | c.1493G>C p.R498P | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV54644915, COSV54647498; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | PolyPhen possibly damaging (0.466); catalogued as rs763562311, COSV59563661; called by muse, mutect2, varscan2
- STXBP5 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs761855511; called by muse, mutect2, varscan2
- STYXL2 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54802904; called by muse, mutect2, varscan2
- TFPI | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1462616601; called by muse, mutect2
- TLR4 | c.645G>T p.M215I (on ENST00000355622 / NM_138554.5; = p.M175I on NM_003266.4) | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62923936; called by muse, mutect2, varscan2
- TMEM132D | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 62/574 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV101396153; called by muse, mutect2, varscan2
- TMEM19 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV57000852; called by muse, mutect2
- TNFSF18 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as rs1349465717; called by muse, mutect2, varscan2
- TPR | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1395168961; called by muse, mutect2
- TRAF1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100875229; called by muse, mutect2
- UGT2B17 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100497315; called by muse, mutect2, varscan2
- ZEB2 | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs76345092; called by muse, mutect2
- ZFPM2 | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 58/685 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65873028; called by muse, mutect2
- ZNF414 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV55321272; called by muse, mutect2, varscan2
- ZNF587B | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100332180; called by muse, mutect2, varscan2
- ZNF716 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV70781758; called by muse, mutect2
- ZNF799 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs544617815; called by muse, mutect2, varscan2
- ZNF99 | c.2015C>A p.T672N | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs769685323, COSV68055549; called by muse, varscan2
- ABCB11 | c.3178C>A p.P1060T | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AC005833.1 | c.1026A>T p.R342S | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS13 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 35/739 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ADCY2 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 55/487 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADGRL3 | c.465G>T p.M155I (on ENST00000506720 / NM_001322402.2; = p.M87I on NM_015236.6) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2
- AFF2 | c.2260C>A p.L754M | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AL592490.1 | c.2123A>T p.Y708F | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALDH9A1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 21/337 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- AMBRA1 | c.3567C>A p.H1189Q (on ENST00000458649 / NM_001367468.1; = p.H1099Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- AMIGO2 | c.400A>C p.N134H | Missense Mutation (SNP) | VAF 17/411 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2
- ANKRD44 | c.2834C>T p.P945L | Missense Mutation (SNP) | VAF 25/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- APCS | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 23/408 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2
- ATP12A | c.2423A>T p.Y808F | Missense Mutation (SNP) | VAF 52/474 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP6V0A4 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 103/933 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ATXN7L2 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BMPER | c.2019G>T p.K673N | Missense Mutation (SNP) | VAF 81/711 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BNC1 | c.1343del p.P448Qfs*35 | Frame Shift Del (DEL) | VAF 42/446 reads (9%) | called by mutect2, pindel
- BPIFB3 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2
- BRD1 | c.387_397del p.P130Qfs*24 | Frame Shift Del (DEL) | VAF 44/356 reads (12%) | called by mutect2, pindel
- BTBD17 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 59/500 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- BTNL9 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C1QTNF6 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.299); called by muse, mutect2
- CCDC85A | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); called by muse, mutect2
- CCDC93 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.22); called by muse, mutect2
- CDH16 | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CDK14 | c.1394C>G p.S465* (on ENST00000380050 / NM_001287135.2; = p.S447* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- CEP350 | c.7763A>G p.Y2588C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CEP89 | c.1268+1del p.X423_splice | Splice Site (DEL) | VAF 12/139 reads (9%) | called by mutect2, pindel
- CES3 | c.603T>A p.D201E | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHN1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNGB1 | c.458+1G>T p.X153_splice | Splice Site (SNP) | VAF 50/521 reads (10%) | called by muse, mutect2
- CNGB3 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 125/858 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL6A6 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPA5 | c.839-1G>T p.X280_splice | Splice Site (SNP) | VAF 44/366 reads (12%) | called by muse, mutect2, varscan2
- CRYGS | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 58/556 reads (10%) | called by muse, mutect2, varscan2
- CSAG1 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 104/469 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD2 | c.5305G>T p.G1769W | Missense Mutation (SNP) | VAF 52/909 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.8278_8279insT p.G2760Vfs*11 (on ENST00000297405 / NM_001363185.1; = p.G2591Vfs*11 on NM_052900.3) | Frame Shift Ins (INS) | VAF 32/356 reads (9%) | called by mutect2, pindel
- CUX1 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3Y | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DEFA6 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DGLUCY | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 23/379 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.391); called by muse, mutect2
- DLGAP3 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 56/609 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- DMGDH | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 72/691 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.1908T>A p.D636E | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.1921G>C p.G641R | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2
- DNALI1 | c.412A>G p.R138G (on ENST00000296218; = p.R116G on NM_003462.5) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- DOCK2 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC3 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- DYDC1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- E2F7 | c.1814A>G p.E605G | Missense Mutation (SNP) | VAF 43/572 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- ELMO1 | c.450-2A>T p.X150_splice | Splice Site (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- EMILIN2 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- EML6 | c.3737G>A p.W1246* | Nonsense Mutation (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- EPHB6 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 33/467 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ERAS | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERBB3 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVL | c.431A>T p.Q144L (on ENST00000402714 / NM_001330221.2; = p.Q146L on NM_016337.3) | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- FARP1 | c.1767A>T p.E589D | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FARP2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 20/675 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- FER1L6 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD4 | c.987A>G p.I329M | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2
- GAS1 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GFI1 | c.939C>A p.D313E | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.761); called by muse, mutect2
- GPR12 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 75/497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- GUSB | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 112/859 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- HDC | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 73/714 reads (10%) | called by muse, mutect2, varscan2
- HERC4 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.081); called by muse, mutect2
- HNF1A | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 69/518 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HOXB7 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2
- HS3ST3B1 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSD17B6 | c.573-2A>T p.X191_splice | Splice Site (SNP) | VAF 26/157 reads (17%) | called by muse, mutect2, varscan2
- IBTK | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- IGKV3D-15 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 31/423 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- IQGAP3 | c.2330G>T p.R777L | Missense Mutation (SNP) | VAF 68/523 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ITGAD | c.2248C>A p.L750M | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAKMIP3 | c.2001+1G>T p.X667_splice | Splice Site (SNP) | VAF 49/435 reads (11%) | called by muse, mutect2, varscan2
- KANK4 | c.2029A>T p.S677C | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KANK4 | c.1251C>A p.D417E | Missense Mutation (SNP) | VAF 53/543 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNK3 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- KDM5C | c.1834G>C p.A612P | Missense Mutation (SNP) | VAF 126/574 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KIF26A | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- KLHL22 | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL4 | c.35A>T p.K12I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- L3MBTL3 | c.2048T>G p.L683R | Missense Mutation (SNP) | VAF 43/465 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- LAMA2 | c.7595C>A p.P2532H | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- LAMA3 | c.9170T>A p.I3057N (on ENST00000313654 / NM_198129.4; = p.I1448N on NM_000227.6) | Missense Mutation (SNP) | VAF 25/770 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- LAMC3 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 112/967 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCP1 | c.1495A>T p.M499L | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LIMK1 | c.1111A>T p.I371F | Missense Mutation (SNP) | VAF 53/541 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); called by muse, mutect2
- LMLN2 | c.1072C>A p.L358I | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.048); called by muse, mutect2
- LRIT1 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC4C | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 65/602 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC7 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- LRRK1 | c.5824G>T p.G1942C | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACC1 | c.115+1G>T p.X39_splice | Splice Site (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- MAPK13 | c.673G>T p.G225W | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MEGF8 | c.7604C>T p.P2535L (on ENST00000251268 / NM_001271938.2; = p.P2468L on NM_001410.3) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MFNG | c.303G>T p.L101= | Splice Region (SNP) | VAF 49/420 reads (12%) | called by muse, mutect2, varscan2
- MMUT | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MPP1 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- MS4A4E | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- MTTP | c.1604A>T p.H535L | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MUC16 | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 45/350 reads (13%) | called by muse, mutect2, varscan2
- MYH13 | c.5799C>A p.S1933R | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- MYOCD | c.2206C>A p.Q736K | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYRF | c.856C>A p.P286T (on ENST00000278836 / NM_001127392.3; = p.P277T on NM_013279.4) | Missense Mutation (SNP) | VAF 52/576 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.558); called by muse, mutect2
- NALCN | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 29/235 reads (12%) | called by muse, varscan2
- NCOA1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- NID1 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 91/647 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- NIN | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- NKX2-4 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- NOS3 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); called by muse, mutect2
- NPHS2 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- NPR3 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 45/453 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NRXN2 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- NT5C2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NXPH2 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OBSCN | c.3626G>T p.S1209I | Missense Mutation (SNP) | VAF 59/718 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- OR10D3 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); called by muse, mutect2
- OR13C8 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2S2 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 80/790 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- OR4A15 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4C16 | c.44T>C p.L15S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- OR5AR1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5H1 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 43/510 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2
- OR6K3 | c.436C>T p.L146F (on ENST00000368146; = p.L130F on NM_001005327.2) | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI3 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 36/439 reads (8%) | called by muse, mutect2
- PADI4 | c.1222G>T p.G408W | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA7 | c.2191G>T p.G731C | Missense Mutation (SNP) | VAF 42/572 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PGS1 | c.1349A>T p.E450V | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PHLPP2 | c.35G>T p.R12M | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- PI15 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- PIEZO2 | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 21/362 reads (6%) | called by muse, mutect2
- PIK3R4 | c.483G>T p.W161C | Missense Mutation (SNP) | VAF 60/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PINX1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 59/500 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.5554C>G p.H1852D | Missense Mutation (SNP) | VAF 63/612 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PKHD1 | c.3008del p.G1003Vfs*13 | Frame Shift Del (DEL) | VAF 51/301 reads (17%) | called by mutect2, pindel, varscan2
- PLCL2 | c.1043T>C p.L348S (on ENST00000615277 / NM_001144382.2; = p.L222S on NM_015184.5) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PLEKHA5 | c.2411A>T p.Y804F | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHA6 | c.2362G>T p.V788L | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- POP7 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.099); called by muse, mutect2
- PRAMEF15 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 44/1036 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRAMEF18 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 23/723 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.024); called by muse, mutect2
- PRAMEF20 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 44/978 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2
- PRAMEF20 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 44/839 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRPF8 | c.5851A>G p.K1951E | Missense Mutation (SNP) | VAF 62/625 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PRRC2A | c.4481G>T p.G1494V | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTH2R | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPN23 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PTPRD | c.1972A>C p.K658Q | Missense Mutation (SNP) | VAF 71/650 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PTPRJ | c.2337A>T p.E779D | Missense Mutation (SNP) | VAF 25/762 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2
- RAMP3 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2
- RCC1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); called by muse, mutect2
- RET | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 101/740 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX1 | c.773A>T p.K258I | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ROBO4 | c.2336G>T p.S779I | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- RPS6KA6 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RTRAF | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- RUBCNL | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 49/471 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RUNX3 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 56/496 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR1 | c.10686+6C>T | Splice Region (SNP) | VAF 62/629 reads (10%) | called by muse, mutect2
- SAGE1 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- SALL3 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SCN5A | c.4106G>C p.G1369A (on ENST00000333535 / NM_198056.3; = p.G1368A on NM_000335.5) | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.414); called by muse, mutect2
- SEC16B | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 17/324 reads (5%) | called by muse, mutect2
- SEC16B | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2
- SETBP1 | c.1721C>A p.T574K | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETBP1 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B4 | c.623A>T p.H208L | Missense Mutation (SNP) | VAF 33/424 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SH3D19 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- SHANK1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SHISAL1 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SI | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A21 | c.530del p.G177Dfs*20 | Frame Shift Del (DEL) | VAF 85/401 reads (21%) | called by mutect2, pindel, varscan2
- SLC35A2 | c.660T>A p.F220L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SLC6A12 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST18 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STXBP5L | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- STXBP5L | c.3530A>C p.K1177T | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TDRD15 | c.5333A>G p.Q1778R | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.165); called by muse, mutect2
- TDRD9 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 26/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEDC1 | c.1061G>T p.G354V (on ENST00000392523 / NM_001367178.1; = p.G285V on NM_001134875.1) | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.059); called by muse, mutect2
- TEP1 | c.5225A>T p.E1742V | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEX13C | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TMTC1 | c.1101G>T p.L367F (on ENST00000539277 / NM_001193451.2; = p.L259F on NM_175861.3) | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TMX4 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TNS3 | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- TRAF7 | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- TRIM10 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 43/441 reads (10%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.498); called by muse, mutect2
- TRIM32 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 78/848 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- TRIM58 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 80/433 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRO | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- TTC22 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- UBASH3A | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 35/568 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- UNC80 | c.4310C>A p.P1437H | Missense Mutation (SNP) | VAF 39/625 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- URB2 | c.3932A>T p.E1311V | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by mutect2, varscan2
- USH1G | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- USP17L1 | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 76/758 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP34 | c.4378G>C p.G1460R | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP36 | c.2433G>T p.K811N | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- VEZT | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- VIPR2 | c.1046T>A p.I349N | Missense Mutation (SNP) | VAF 64/669 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2
- VPS13B | c.2176C>T p.L726F | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WNK2 | c.5101G>T p.A1701S (on ENST00000297954 / NM_001282394.1; = p.A1664S on NM_006648.3) | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ZC3H12B | c.2429C>A p.A810E | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZDHHC15 | c.839T>G p.F280C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by mutect2, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- ZNF41 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF729 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF780A | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 33/220 reads (15%) | called by muse, mutect2, varscan2
- ZNF845 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AANAT | c.123C>A p.T41= | Silent (SNP) | VAF 62/423 reads (15%) | called by muse, mutect2, varscan2
- AMOT | c.1209A>T p.P403= | Silent (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- ANK2 | c.8376T>C p.G2792= | Silent (SNP) | VAF 36/374 reads (10%) | called by muse, mutect2, varscan2
- ANKRD60 | c.873C>T p.S291= | Silent (SNP) | VAF 34/482 reads (7%) | called by muse, mutect2
- ARHGEF11 | c.4263C>T p.D1421= | Silent (SNP) | VAF 52/326 reads (16%) | catalogued as rs151281059; called by muse, mutect2, varscan2
- ASTN2 | c.945C>A p.G315= | Silent (SNP) | VAF 15/176 reads (9%) | catalogued as COSV57803113; called by muse, mutect2
- ASXL3 | c.4461G>C p.L1487= | Silent (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- AVPR1B | c.1161C>A p.A387= | Silent (SNP) | VAF 32/564 reads (6%) | called by muse, mutect2
- BSND | c.564C>A p.P188= | Silent (SNP) | VAF 23/382 reads (6%) | catalogued as COSV100987637; called by muse, mutect2
- BTBD8 | c.5295G>T p.A1765= (on ENST00000636805 / NM_001376131.1; = p.A1252= on NM_015237.4) | Silent (SNP) | VAF 23/234 reads (10%) | called by muse, mutect2
- CDH23 | c.504C>A p.L168= | Silent (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- CDH6 | c.2082C>T p.P694= | Silent (SNP) | VAF 51/434 reads (12%) | catalogued as rs764269155, COSV54078647, COSV99420279; called by muse, mutect2, varscan2
- CIITA | c.2172G>T p.L724= | Silent (SNP) | VAF 86/754 reads (11%) | called by muse, mutect2, varscan2
- CNGB1 | c.1368A>T p.S456= | Silent (SNP) | VAF 68/790 reads (9%) | called by muse, mutect2
- CNTN3 | c.1923G>T p.V641= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as COSV55166945; called by muse, mutect2, varscan2
- COL6A6 | c.4812C>G p.P1604= | Silent (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2, varscan2
- CPA3 | c.274T>C p.L92= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- CSMD2 | c.4737C>T p.S1579= | Silent (SNP) | VAF 29/551 reads (5%) | catalogued as rs969908233; called by muse, mutect2
- CTNND2 | c.2598G>T p.A866= | Silent (SNP) | VAF 54/402 reads (13%) | catalogued as COSV58881028; called by muse, mutect2, varscan2
- DCHS1 | c.8292A>G p.T2764= | Silent (SNP) | VAF 79/836 reads (9%) | catalogued as rs763012228; ClinVar: benign; called by muse, mutect2
- DLGAP3 | c.570G>T p.P190= | Silent (SNP) | VAF 54/606 reads (9%) | catalogued as COSV99332050; called by muse, mutect2
- E2F8 | c.1674C>T p.S558= | Silent (SNP) | VAF 80/786 reads (10%) | catalogued as rs763917035; called by muse, mutect2
- ERN2 | c.675G>T p.L225= | Silent (SNP) | VAF 20/584 reads (3%) | called by muse, mutect2
- FAM47C | c.2037C>T p.C679= | Silent (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- FDXR | c.828G>C p.L276= (on ENST00000293195 / NM_024417.5; = p.L282= on NM_004110.6) | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- FGF23 | c.609G>T p.P203= | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as COSV99426727; called by muse, mutect2, varscan2
- GDF10 | c.840C>T p.P280= | Silent (SNP) | VAF 35/332 reads (11%) | called by muse, mutect2, varscan2
- GPM6A | c.297G>A p.L99= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as COSV54533479; called by muse, mutect2
- GPR26 | c.213G>T p.R71= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- GPR26 | c.700C>A p.R234= | Silent (SNP) | VAF 27/301 reads (9%) | catalogued as rs777716254; called by muse, mutect2
- GRID1 | c.1923G>T p.T641= | Silent (SNP) | VAF 21/254 reads (8%) | catalogued as rs747030971, COSV100027047; called by muse, mutect2
- HSP90AB1 | c.555T>C p.L185= | Silent (SNP) | VAF 45/451 reads (10%) | called by muse, mutect2
- IGFBP5 | c.759C>A p.G253= | Silent (SNP) | VAF 30/490 reads (6%) | called by muse, mutect2
- ILDR2 | c.585G>C p.L195= | Silent (SNP) | VAF 66/401 reads (16%) | catalogued as COSV99614113; called by muse, mutect2, varscan2
- JADE3 | c.378C>T p.I126= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- KCNA5 | c.1728C>G p.A576= | Silent (SNP) | VAF 41/465 reads (9%) | called by muse, mutect2
- KIF1A | c.4822C>A p.R1608= (on ENST00000320389 / NM_001379639.1; = p.R1600= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/400 reads (5%) | catalogued as COSV57503238; called by muse, mutect2
- KNG1 | c.912G>T p.V304= | Silent (SNP) | VAF 44/474 reads (9%) | called by muse, mutect2
- KRT37 | c.636G>A p.K212= | Silent (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- LRFN2 | c.1911G>T p.R637= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as COSV57830064; called by muse, mutect2
- MAGEB6 | c.1033C>A p.R345= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as COSV100983666, COSV66872362; called by muse, mutect2, varscan2
- MARCHF11 | c.771C>A p.A257= | Silent (SNP) | VAF 16/334 reads (5%) | catalogued as COSV100198109, COSV60126949; called by muse, mutect2
- MED12 | c.888G>T p.R296= | Silent (SNP) | VAF 80/309 reads (26%) | called by muse, mutect2, varscan2
- MEGF9 | c.1350C>T p.I450= | Silent (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2, varscan2
- MISP | c.1323C>T p.F441= | Silent (SNP) | VAF 62/540 reads (11%) | catalogued as rs185675116; called by muse, mutect2, varscan2
- MRGPRX1 | c.672C>A p.V224= | Silent (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
- MRGPRX2 | c.216C>A p.A72= | Silent (SNP) | VAF 47/373 reads (13%) | catalogued as rs758641595; called by muse, mutect2, varscan2
- MUC12 | c.16207C>T p.L5403= (on ENST00000379442; = p.L5260= on NM_001164462.1) | Silent (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- MUC16 | c.18558C>T p.A6186= | Silent (SNP) | VAF 15/482 reads (3%) | catalogued as rs888677303; called by muse, mutect2
- MYO1F | c.555C>A p.G185= | Silent (SNP) | VAF 63/561 reads (11%) | called by muse, mutect2, varscan2
- MYO7A | c.3267C>A p.A1089= | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as COSV101289167; called by muse, mutect2
- NELL2 | c.1248G>T p.L416= | Silent (SNP) | VAF 26/478 reads (5%) | called by muse, mutect2
- NF1 | c.6399G>T p.L2133= (on ENST00000358273 / NM_001042492.3; = p.L2112= on NM_000267.3) | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as CD1311362; called by muse, mutect2
- NOX3 | c.651G>T p.L217= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs934813272; called by muse, varscan2
- NRXN2 | c.4152A>T p.T1384= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- OR2G3 | c.729C>A p.S243= | Silent (SNP) | VAF 45/269 reads (17%) | catalogued as COSV100180538; called by muse, mutect2, varscan2
- OR4A15 | c.621C>A p.V207= | Silent (SNP) | VAF 20/446 reads (4%) | catalogued as COSV59036498; called by muse, mutect2
- OR52B2 | c.333G>T p.V111= | Silent (SNP) | VAF 15/400 reads (4%) | called by muse, mutect2
- OR5AC2 | c.234T>C p.S78= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- OTOP1 | c.12C>A p.G4= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- PCDHA2 | c.1225C>T p.L409= | Silent (SNP) | VAF 63/590 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.540G>T p.L180= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- PCSK4 | c.741G>A p.L247= | Silent (SNP) | VAF 25/210 reads (12%) | catalogued as rs1400431214; called by muse, mutect2, varscan2
- PDGFRB | c.1189C>A p.R397= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as COSV55803933; called by muse, mutect2
- PIGR | c.36C>G p.V12= | Silent (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- PLCXD3 | c.930C>A p.L310= | Silent (SNP) | VAF 30/321 reads (9%) | called by muse, mutect2
- PLPPR4 | c.948A>T p.G316= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV64566414; called by muse, mutect2
- POGLUT2 | c.567A>T p.L189= | Silent (SNP) | VAF 52/284 reads (18%) | called by muse, mutect2, varscan2
- POLM | c.846C>T p.H282= | Silent (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- PRKCB | c.1563C>A p.S521= | Silent (SNP) | VAF 30/367 reads (8%) | catalogued as COSV57772830; called by muse, mutect2
- SCN4A | c.2148G>T p.V716= | Silent (SNP) | VAF 83/659 reads (13%) | catalogued as COSV101438337; called by muse, mutect2, varscan2
- SEMA5B | c.2772T>A p.A924= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- SLC10A1 | c.84C>T p.S28= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as rs1434384653, COSV53681755; ClinVar: uncertain significance; called by muse, mutect2
- SLC17A4 | c.156C>A p.T52= | Silent (SNP) | VAF 65/723 reads (9%) | catalogued as COSV100930686; called by muse, mutect2
- SLC6A17 | c.1932C>A p.L644= | Silent (SNP) | VAF 50/604 reads (8%) | catalogued as rs1162798273; called by muse, mutect2
- STYXL2 | c.1356G>A p.K452= | Silent (SNP) | VAF 33/220 reads (15%) | called by muse, mutect2, varscan2
- TMC2 | c.2610C>T p.H870= | Silent (SNP) | VAF 34/610 reads (6%) | called by muse, mutect2
- TMUB2 | c.882A>G p.Q294= (on ENST00000538716 / NM_001353177.2; = p.Q274= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/432 reads (7%) | catalogued as rs373097050; called by muse, mutect2
- TOR4A | c.156C>T p.D52= | Silent (SNP) | VAF 57/321 reads (18%) | catalogued as rs1395288149; called by muse, mutect2, varscan2
- TRGV4 | c.144C>T p.T48= | Silent (SNP) | VAF 89/789 reads (11%) | catalogued as rs746908068; called by muse, mutect2, varscan2
- TRPS1 | c.3201T>A p.P1067= (on ENST00000220888 / NM_001330599.2; = p.P1080= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/892 reads (19%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2193T>A p.I731= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2
- VIPR2 | c.1044C>A p.P348= | Silent (SNP) | VAF 62/670 reads (9%) | called by muse, mutect2
- ZBED6 | c.357A>T p.I119= | Silent (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- ZNF385D | c.1008A>G p.L336= | Silent (SNP) | VAF 39/462 reads (8%) | catalogued as rs762734111; called by muse, mutect2
- ZNF638 | c.408A>C p.T136= | Silent (SNP) | VAF 41/421 reads (10%) | called by muse, mutect2
- AC002511.3 | n.392T>A | RNA (SNP) | VAF 43/386 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4877C>A | RNA (SNP) | VAF 38/260 reads (15%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3521C>T | RNA (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- AC073621.1 | n.490G>T | RNA (SNP) | VAF 15/228 reads (7%) | called by muse, mutect2
- ADAM23 | c.2360-4050A>T | Intron (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- AOAH | c.*84C>A | 3'UTR (SNP) | VAF 78/827 reads (9%) | called by muse, mutect2
- ARHGEF4 | chr2:130916435 A>T | 5'Flank (SNP) | VAF 11/129 reads (9%) | catalogued as rs909596269; called by muse, mutect2
- ASXL1 | c.57+463G>T | Intron (SNP) | VAF 38/575 reads (7%) | called by muse, mutect2
- BRD4 | c.2158+539C>T | Intron (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- C10orf90 | c.1243+1170T>A | Intron (SNP) | VAF 7/133 reads (5%) | catalogued as rs1462073276; called by muse, mutect2
- C15orf40 | c.366+75A>C | Intron (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- C3P1 | n.3465C>T | RNA (SNP) | VAF 78/788 reads (10%) | catalogued as rs773425061; called by muse, mutect2, varscan2
- C4orf3 | chr4:119300725 C>A | 5'Flank (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CAPRIN2 | c.2318-303A>G | Intron (SNP) | VAF 13/278 reads (5%) | catalogued as rs1189313059; called by muse, mutect2
- CCDC150 | c.1441-135G>T | Intron (SNP) | VAF 32/390 reads (8%) | called by muse, mutect2
- CCDC74B | c.296-204C>T | Intron (SNP) | VAF 40/547 reads (7%) | catalogued as rs1252625017; called by muse, mutect2
- CCL3L3 | c.76+228T>A | Intron (SNP) | VAF 66/2498 reads (3%) | called by muse, mutect2
- CHP2 | c.140+14G>T | Intron (SNP) | VAF 21/429 reads (5%) | called by muse, mutect2
- CLRN1 | c.*546C>A | 3'UTR (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- DACT3 | c.499+14G>C | Intron (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- DENND10 | chr10:119104087 G>T | 5'Flank (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- FAM161A | c.*494G>T | 3'UTR (SNP) | VAF 32/414 reads (8%) | called by muse, mutect2
- FCSK | c.235-72T>G | Intron (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- FGFR1 | c.-3G>T | 5'UTR (SNP) | VAF 19/390 reads (5%) | catalogued as COSV100248589, COSV58337863; called by muse, mutect2
- FLJ40194 | n.355T>C | RNA (SNP) | VAF 65/608 reads (11%) | catalogued as rs748895517; called by muse, mutect2, varscan2
- FRMD8P1 | n.855C>A | RNA (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- GRAMD1B | c.2127+136G>T | Intron (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- GRAMD1C | c.953-2618G>T | Intron (SNP) | VAF 27/298 reads (9%) | called by muse, mutect2
- GRHPR | c.734+30del | Intron (DEL) | VAF 58/418 reads (14%) | called by mutect2, pindel, varscan2
- GRM6 | c.2125-135C>T | Intron (SNP) | VAF 14/318 reads (4%) | catalogued as rs911863561; called by muse, mutect2
- GUCY2EP | n.1737G>T | RNA (SNP) | VAF 46/367 reads (13%) | called by muse, mutect2, varscan2
- HAS2-AS1 | n.774T>G | RNA (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.198+10487C>G | Intron (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- HSD17B7P2 | n.582C>G | RNA (SNP) | VAF 44/355 reads (12%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.-8A>T | 5'UTR (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- ITGA4 | c.556+581G>C | Intron (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- KLF8 | c.-70A>G | 5'UTR (SNP) | VAF 22/124 reads (18%) | catalogued as rs1299377998; called by muse, mutect2
- LGI4 | c.793+29T>C | Intron (SNP) | VAF 24/191 reads (13%) | catalogued as rs1226584365; called by muse, mutect2, varscan2
- LRATD1 | c.*714dup | 3'UTR (INS) | VAF 38/375 reads (10%) | called by mutect2, pindel
- MPRIP | c.2164-4310G>T | Intron (SNP) | VAF 38/736 reads (5%) | called by muse, mutect2
- NBPF11 | c.-548-2842G>T | Intron (SNP) | VAF 58/385 reads (15%) | called by muse, mutect2, varscan2
- NDUFS4 | c.177+1345C>T | Intron (SNP) | VAF 28/228 reads (12%) | called by mutect2, varscan2
- NPEPL1 | c.1001+10G>T | Intron (SNP) | VAF 58/703 reads (8%) | called by muse, mutect2
- NPEPL1 | c.1001+149G>T | Intron (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- NRXN1 | c.3365-109775C>T | Intron (SNP) | VAF 58/746 reads (8%) | catalogued as COSV58434961; called by muse, mutect2
- OBSCN | c.5138-1739G>T | Intron (SNP) | VAF 45/824 reads (5%) | called by muse, mutect2
- OR4C4P | n.840T>C | RNA (SNP) | VAF 23/219 reads (11%) | catalogued as rs74415452; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67345A>T | Intron (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- PPIAP58 | chr19:29923702 G>T | 3'Flank (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- PRRG3 | c.8-14G>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- PTGES3 | c.*73C>T | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- RASGRP2 | c.-71-115G>T | Intron (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- RNF17 | c.1240+847C>A | Intron (SNP) | VAF 16/213 reads (8%) | called by muse, mutect2
- SCN3B | c.-21G>T | 5'UTR (SNP) | VAF 22/488 reads (5%) | called by muse, mutect2
- SEC14L1 | c.-240+45G>T | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- SEPTIN5 | c.55-2330G>T | Intron (SNP) | VAF 58/402 reads (14%) | called by muse, mutect2, varscan2
- SHANK2 | c.1174+33096G>T | Intron (SNP) | VAF 38/891 reads (4%) | called by muse, mutect2
- SHISA4 | c.-36T>C | 5'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- SLAMF8 | chr1:159841186 C>A | 3'Flank (SNP) | VAF 56/446 reads (13%) | called by muse, mutect2, varscan2
- SLC22A7 | c.399+98C>A | Intron (SNP) | VAF 104/496 reads (21%) | called by muse, mutect2, varscan2
- SLIT3 | c.1459+4542G>T | Intron (SNP) | VAF 51/469 reads (11%) | called by muse, mutect2, varscan2
- SLIT3 | c.1459+4541G>T | Intron (SNP) | VAF 51/478 reads (11%) | called by muse, mutect2, varscan2
- TOX2 | c.*47G>T | 3'UTR (SNP) | VAF 63/587 reads (11%) | called by muse, mutect2, varscan2
- UAP1L1 | chr9:137086525 C>A | 3'Flank (SNP) | VAF 41/265 reads (15%) | called by muse, mutect2, varscan2
- WDR92 | c.-69C>G | 5'UTR (SNP) | VAF 32/465 reads (7%) | catalogued as rs753884202; called by muse, mutect2
- ZNF486 | c.-103C>A | 5'UTR (SNP) | VAF 44/296 reads (15%) | called by muse, mutect2, varscan2
